Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GC-06A (Metastatic).

DIAGNOSIS

A) LEFT AXILLARY CONTENTS, LEVELS I, II AND III:

METASTATIC MELANOMA IN ELEVEN OF TWENTY-SEVEN LYMPH NODES (11/27).

LARGEST SIZE IS 47.0 MM.

TUMOR IS SUBCAPSULAR AND INTRAPARENCHYMAL.

EXTRANODAL EXTENSION IS PRESENT.

ICD O-3
Melanoma, NOS 8720/3
Site Axillary lymph node
877.3

Entire report and diagnosis completed by

pw 11/27/13

GROSS DESCRIPTION

A) LEFT AXILLARY CONTENTS LEVEL I, II AND III - Received is an unoriented fragment of yellow-tan to red fibrofatty tissue measuring 17.3 x 12.1 x 3.2 cm in greatest dimension. The specimen is serially sectioned revealing twenty-seven possible lymph node-like structures ranging in size from 4.7 x 3.2 x 2.1 cm to 0.3 x 0.2 x 0.2 cm in greatest dimension respectively. Three grossly positive appearing possible lymph nodes are noted and representative portions of each are submitted in cassettes A1-A3. Seven additional possible lymph nodes are bisected and submitted with each one in cassettes A4-A10. The remaining lymph nodes are submitted in cassettes A11, two possible lymph nodes; A12, three possible lymph nodes; A13, three possible lymph nodes; A14, three possible lymph nodes; A15, three possible lymph nodes; A16, three possible lymph nodes.

CLINICAL HISTORY

Melanoma, metastatic to left axilla.

SNOMED CODES

T-C4710, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 03ae59fe-9988-450d-9dd1-5751e8bbf4a7 (TCGA-D3-A8GC.2ED84430-A136-4A59-87EE-A9B7147BD719.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).